Somatic mutation profile of tumor specimen MP2PRT-PATHBD-TMP1-A (aliquot MP2PRT-PATHBD-TMP1-A-1-0-D-A82L-36) from MP2PRT case MP2PRT-PATHBD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,098 days).
Specimen MP2PRT-PATHBD-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 47533692-a25a-46f1-b558-278d7f8c7240.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATHBD-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATHBD-NB1-A-1-0-D-A82L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/05329efc-7b72-4e4d-b253-788aa3f14803

The open-access MAF lists 19 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 11, Silent 4, Nonsense Mutation 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFP | c.1183G>T p.D395Y | Missense Mutation (SNP) | VAF 37/219 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.915); catalogued as COSV99889824; called by muse, mutect2, varscan2
- CNTNAP5 | c.448C>T p.R150* | Nonsense Mutation (SNP) | VAF 46/530 reads (9%) | catalogued as COSV70505946; called by muse, mutect2
- GPATCH2L | c.889C>T p.R297W | Missense Mutation (SNP) | VAF 13/328 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs1186846348, COSV55050844; called by muse, mutect2
- NPY2R | c.871G>A p.V291I | Missense Mutation (SNP) | VAF 93/483 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs147783618, COSV61527392; called by muse, mutect2, varscan2
- XCR1 | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 58/418 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs746145944, COSV58570861; called by muse, mutect2, varscan2
- ARHGAP5 | c.2334G>C p.L778F | Missense Mutation (SNP) | VAF 14/506 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- ATR | c.6789_6790insC p.S2264Lfs*16 | Frame Shift Ins (INS) | VAF 48/293 reads (16%) | called by mutect2, pindel*, varscan2
- ESPN | c.541C>T p.Q181* | Nonsense Mutation (SNP) | VAF 100/647 reads (15%) | called by muse, mutect2, varscan2
- IRAG2 | c.3666G>T p.R1222S (on ENST00000636465; = p.R267S on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/470 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KIF7 | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 23/626 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KLK13 | c.659G>C p.G220A | Missense Mutation (SNP) | VAF 56/344 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MUC17 | c.11227A>G p.M3743V | Missense Mutation (SNP) | VAF 96/587 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- OR51Q1 | c.662C>A p.T221K | Missense Mutation (SNP) | VAF 59/374 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- TRGV4 | c.348_354delinsAGCA p.W116_G118delins* | Nonsense Mutation (DEL) | VAF 36/100 reads (36%) | called by pindel, varscan2*
- USP9Y | c.2416A>G p.K806E | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2
- FAM83B | c.2787T>G p.T929= | Silent (SNP) | VAF 75/467 reads (16%) | catalogued as rs773902585; called by muse, mutect2, varscan2
- LMTK2 | c.2976G>A p.P992= | Silent (SNP) | VAF 52/500 reads (10%) | catalogued as rs755576900; called by muse, mutect2
- PLEKHF1 | c.465G>A p.T155= | Silent (SNP) | VAF 147/791 reads (19%) | catalogued as rs759539825, COSV101460772; called by muse, mutect2, varscan2
- PRR23B | c.735C>T p.H245= | Silent (SNP) | VAF 20/530 reads (4%) | catalogued as rs1322951360, COSV61493461, COSV61494304; called by muse, mutect2
